Surgical pathology report (de-identified scan), TCGA case TCGA-4Z-AA7M, project TCGA-BLCA (Bladder Urothelial Carcinoma), tissue source site Barretos Cancer Hospital, specimen TCGA-4Z-AA7M-01A (Primary Tumor).

Collect date: _____

(MM/DD/YYYY)

ICD-O-3
Carcinoma, transitional cell NOS
Site: Bladder, lateral wall
path
Bladder NOS
812013
C67.2
C67.9
7/23/14

PATHOLOGY REPORT:

PRIMARY SITE: Bladder

1 - "Bladder + prostate":

High-grade urothelial carcinoma of the bladder characterized as follows:

- . Measure of neoplasia in its major axis: 6.2 cm
- . Ulcerated and infiltrative neoplasia affecting all layers of the bladder and perivisceral fat.
- . Prostate, seminal vesicles, vas deferens, ureters and urethra free of neoplastic involvement.
- . Neural infiltration not observed.
- . Lymphatic vascular invasion not detected.
- . Sanguineous vascular invasion not detected.
- . Surgical margins free of neoplastic involvement.
- Ulcerated granulomatous cystitis.

Acinar adenocarcinoma of the prostate associated, characterized as follows:

Measure of neoplasia in its major axis: 0.5 cm

- . Located between the base and left mid-zone.
- . Gleason score 6 (3+3).
- . Neural infiltration not observed.
- . Lymphatic vascular invasion not detected.
- . Sanguineous vascular invasion not detected.
- . Surgical margins free of neoplastic involvement.
- Lymph nodes free of neoplastic involvement (0/3)

2 - "Right pelvic lymphadenectomy":

Free of neoplastic involvement (0/6).

3 - "Left pelvic lymphadenectomy":

Lymph nodes free of neoplastic involvement (0/19)

PATHOLOGICAL STAGING

Topography	Morphology	Stage
Bladder, NOS	Transitional cell carcinoma, NOS	pT3 pN0

Source: NCI Genomic Data Commons file c388aa2e-1ccb-4e9b-b630-ae5c4fa507cb (TCGA-4Z-AA7M.C14C42D1-6359-4625-90E1-B3E43646DB64.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).